Somatic mutation profile of tumor specimen BA2926D (aliquot aq-BA2926D) from BEATAML1.0 case 2185, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.6 years (21,387 days).
Specimen BA2926D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 358fb247-a95a-4c48-887f-3335a626b55a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2556D (Solid Tissue Normal), aliquot aq-BA2556D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09d5a81b-c3fa-44c8-a825-16054fa02249

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131692272, COSV100418496; ClinVar: pathogenic; called by muse, mutect2
- ANKRD35 | c.1529G>C p.R510P | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs201815402, COSV62909548, COSV62911775, COSV99053003; called by muse, mutect2, varscan2
- CNOT2 | c.113A>G p.H38R | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.014); catalogued as rs141549168, COSV57501966; called by muse, mutect2, varscan2
- CNTNAP5 | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 100/198 reads (51%) | catalogued as rs768209651, COSV70475052; called by muse, varscan2
- DNMT3A | c.890G>A p.W297* | Nonsense Mutation (SNP) | VAF 68/84 reads (81%) | catalogued as rs944608317, COSV53073228; called by muse, mutect2, varscan2
- MUC16 | c.16693G>A p.V5565I | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750565064, COSV67453893; called by muse, mutect2, varscan2
- SLC12A7 | c.1430T>C p.I477T | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs1193976119; called by muse, mutect2, varscan2
- CTSF | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HTR4 | c.155A>G p.K52R | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, varscan2
- OPLAH | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFAS | c.3704A>T p.E1235V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRMO | c.1069G>T p.V357F | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.202); called by muse, mutect2
- ZBED6CL | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- DNAH9 | c.9729G>A p.P3243= | Silent (SNP) | VAF 176/392 reads (45%) | catalogued as rs149731222; called by muse, mutect2, varscan2
- FSIP2 | c.3564C>T p.T1188= | Silent (SNP) | VAF 98/256 reads (38%) | called by muse, mutect2, varscan2
- MXRA5 | c.7086C>T p.D2362= | Silent (SNP) | VAF 77/92 reads (84%) | catalogued as rs142440634; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1398C>T p.D466= (on ENST00000352766; = p.D387= on NM_181334.5) | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs142806387; called by muse, mutect2, varscan2
- SMTNL2 | c.1143C>T p.S381= (on ENST00000389313 / NM_001114974.2; = p.S237= on NM_198501.3) | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs377118143; called by muse, mutect2, varscan2
